Somatic mutation profile of tumor specimen TCGA-P3-A5Q6-01A (aliquot TCGA-P3-A5Q6-01A-11D-A28R-08) from TCGA case TCGA-P3-A5Q6, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 49.1 years (17,917 days).
Specimen TCGA-P3-A5Q6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3421b3d3-e961-451d-b452-e2b607533d19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A5Q6-10A (Blood Derived Normal), aliquot TCGA-P3-A5Q6-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d3ef85a-b5d5-461e-8ae9-b47895115ed9

The open-access MAF lists 138 somatic variants for this specimen: 97 protein-altering or splice-affecting, 35 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 35, Nonsense Mutation 7, Intron 3, In Frame Del 2, Frame Shift Ins 2, 5'Flank 1, Splice Region 1, RNA 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 33/55 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2245C>T p.R749* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as rs1323297861, COSV55948448; called by muse, mutect2, varscan2
- ABCB5 | c.3052C>T p.R1018* (on ENST00000404938 / NM_001163941.2; = p.R573* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as rs200343372; called by muse, mutect2, varscan2
- ABTB1 | c.997G>A p.V333M (on ENST00000232744 / NM_172027.3; = p.V191M on NM_032548.3) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs770731601, COSV51743066; called by muse, mutect2, varscan2
- AC092718.8 | c.171C>G p.H57Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100202917; called by muse, mutect2, varscan2
- ADGRG6 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.157); catalogued as COSV99749101; called by muse, mutect2, varscan2
- AGBL1 | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as rs774583786, COSV101224369; called by muse, mutect2, varscan2
- AK9 | c.633A>G p.A211= | Splice Region (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99572829; called by muse, mutect2
- ANKRD11 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV99970837; called by muse, mutect2, varscan2
- ASPG | c.71G>A p.S24N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV101496461; called by muse, mutect2, varscan2
- B3GAT1 | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100438244; called by muse, mutect2, varscan2
- BICD2 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV100794381; called by muse, mutect2, varscan2
- BSDC1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.787); catalogued as COSV100345198; called by muse, mutect2, varscan2
- C3 | c.966G>C p.K322N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.552); catalogued as COSV99837381; called by muse, mutect2, varscan2
- CACNA1S | c.5617C>A p.L1873M | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100755431, COSV62936605; called by muse, mutect2, varscan2
- CCT8L2 | c.1526A>G p.E509G | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as rs565967987, COSV100743197; called by muse, mutect2, varscan2
- CD19 | c.1360T>G p.S454A | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100218296; called by muse, mutect2, varscan2
- CDC42BPB | c.810C>G p.C270W | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775695; called by muse, mutect2, varscan2
- CENPL | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs754472381, COSV61892419; called by mutect2, varscan2
- CEP126 | c.2371A>G p.T791A | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99681529; called by muse, mutect2, varscan2
- CEP350 | c.8479G>C p.E2827Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV100855384; called by muse, mutect2, varscan2
- CNGB1 | c.2026G>A p.V676M | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as rs1452697207, COSV99212274; called by muse, mutect2, varscan2
- COL28A1 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs561741584, COSV101258993; called by muse, mutect2, varscan2
- CRYBG3 | c.6522G>T p.Q2174H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV99477611; called by muse, mutect2, varscan2
- DPYSL2 | c.510C>G p.F170L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100234289; called by muse, mutect2, varscan2
- DSEL | c.2869C>G p.L957V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV100026170; called by muse, mutect2, varscan2
- EFCAB5 | c.3446G>C p.S1149T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs982556390, COSV100300882; called by muse, mutect2, varscan2
- EGFLAM | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 162/387 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100380884; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs755958296, COSV57519082; called by muse, mutect2, varscan2
- EPHA5 | c.1038G>C p.E346D | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99901734; called by muse, mutect2, varscan2
- FAM204A | c.239T>A p.F80Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100977348, COSV100977388; called by muse, mutect2
- FOXA2 | c.551A>G p.E184G (on ENST00000377115 / NM_153675.3; = p.E190G on NM_021784.5) | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV101008537; called by muse, mutect2, varscan2
- FRYL | c.6247C>G p.L2083V | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99978403; called by muse, mutect2, varscan2
- GJB4 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1375118836, COSV58357266; called by muse, mutect2, varscan2
- GPR156 | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100251770; called by muse, mutect2
- GREB1 | c.4481T>A p.F1494Y | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99303962; called by muse, mutect2, varscan2
- GRSF1 | c.1326A>T p.E442D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99636098; called by muse, mutect2, varscan2
- GUCY1A2 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs765178829, COSV56484063, COSV99977339; called by muse, mutect2, varscan2
- HPS1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100282846; called by muse, mutect2, varscan2
- IRAG2 | c.3354G>T p.L1118F (on ENST00000636465; = p.L163F on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100611903; called by muse, mutect2, varscan2
- KCNS3 | c.452T>G p.L151R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.265); catalogued as COSV100411533; called by muse, mutect2, varscan2
- LIMCH1 | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs751602376, COSV100573175, COSV100574657; called by muse, mutect2, varscan2
- LPAR1 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.868); catalogued as COSV100731058; called by muse, mutect2, varscan2
- LRP1B | c.10468C>T p.P3490S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101261909; called by muse, mutect2, varscan2
- MAP3K14 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100766585; called by muse, mutect2, varscan2
- MECOM | c.2809G>T p.E937* (on ENST00000468789 / NM_001105078.4; = p.E1125* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 23/579 reads (4%) | catalogued as COSV99245704; called by muse, mutect2
- MSH3 | c.3359A>T p.Q1120L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99435973; called by muse, mutect2, varscan2
- MUC13 | c.335T>G p.V112G | Missense Mutation (SNP) | VAF 103/323 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100222522; called by muse, mutect2, varscan2
- MYNN | c.1745C>G p.T582S | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100582363; called by muse, mutect2
- NACA2 | c.512T>G p.V171G | Missense Mutation (SNP) | VAF 97/196 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101478579; called by muse, mutect2, varscan2
- NDST4 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.41); catalogued as COSV99998130; called by muse, mutect2, varscan2
- NELL1 | c.1003T>C p.C335R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100125819; called by muse, mutect2, varscan2
- NIPBL | c.5051C>G p.T1684R | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as CD107699, COSV99243064; called by muse, mutect2, varscan2
- NUMA1 | c.500A>G p.E167G | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV100706688; called by muse, mutect2, varscan2
- OCA2 | c.946C>A p.L316I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.11); catalogued as COSV100668820; called by muse, mutect2, varscan2
- OFD1 | c.1604T>C p.L535S | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100407189; called by muse, mutect2, varscan2
- OR52E2 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100384953; called by muse, mutect2, varscan2
- P3H1 | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV99355549; called by muse, mutect2, varscan2
- PAX9 | c.480C>A p.Y160* | Nonsense Mutation (SNP) | VAF 31/93 reads (33%) | catalogued as CM119119, COSV100825911; called by muse, mutect2, varscan2
- PDZRN4 | c.1810G>A p.E604K (on ENST00000402685 / NM_001164595.2; = p.E346K on NM_013377.4) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV100113828, COSV54219627; called by muse, mutect2, varscan2
- PLPPR4 | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100926668, COSV100926963; called by muse, mutect2, varscan2
- PPP3CB | c.483A>T p.E161D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100646307; called by muse, mutect2, varscan2
- PSTK | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs79236806, COSV100924798; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1573C>T p.R525W (on ENST00000421990 / NM_001136042.2; = p.R507W on NM_025267.3) | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs763918882, COSV100799497; called by muse, mutect2, varscan2
- RFC2 | c.997T>G p.S333A (on ENST00000055077 / NM_181471.3; = p.S299A on NM_002914.4) | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV99278155; called by muse, mutect2, varscan2
- RPGRIP1L | c.848C>A p.S283* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100046943; called by muse, mutect2, varscan2
- RTN4 | c.590A>T p.E197V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100464103; called by muse, mutect2, varscan2
- RUNDC3B | c.549A>T p.E183D | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); catalogued as COSV100407357; called by muse, mutect2, varscan2
- RYR1 | c.8581G>A p.D2861N | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs138647599; called by muse, mutect2, varscan2
- SLC24A4 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs540116512, COSV100106384; called by muse, mutect2, varscan2
- SORBS1 | c.1389A>T p.R463S (on ENST00000361941 / NM_001034954.2; = p.R253S on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.045); catalogued as COSV99529074; called by muse, mutect2, varscan2
- SPIC | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100163101; called by muse, mutect2, varscan2
- STK31 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100670030; called by muse, mutect2, varscan2
- TAS2R20 | c.658A>G p.S220G | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV101115805, COSV67855794; called by muse, mutect2, varscan2
- TASOR | c.2116A>T p.S706C (on ENST00000355628 / NM_001365636.2; = p.S310C on NM_015224.3) | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV100843712; called by muse, mutect2, varscan2
- TBC1D10A | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV99305021; called by muse, mutect2
- TBC1D32 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99251523; called by muse, mutect2, varscan2
- TMEM117 | c.735T>G p.F245L | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.953); catalogued as COSV99863922; called by muse, mutect2, varscan2
- TNR | c.1763C>G p.T588S | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as COSV54880225, COSV99691960; called by muse, mutect2, varscan2
- TRIM49 | c.1141G>T p.G381W | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100316273; called by muse, mutect2, varscan2
- TSHZ2 | c.3091G>A p.V1031M | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1017257990, COSV61588669; called by muse, mutect2, varscan2
- TTC39C | c.383G>A p.R128Q (on ENST00000317571 / NM_001135993.2; = p.R67Q on NM_153211.4) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs779953904, COSV100455654; called by muse, mutect2, varscan2
- UBOX5 | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV53908202; called by muse, mutect2, varscan2
- USH2A | c.2161G>A p.V721I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs776935886, COSV100243631; called by muse, mutect2, varscan2
- USP13 | c.902C>T p.T301I | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99831846; called by muse, mutect2
- VCP | c.1922A>T p.Q641L | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100734381; called by muse, mutect2, varscan2
- WDR92 | c.647A>T p.E216V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99718540; called by muse, mutect2, varscan2
- ZC3H7B | c.2296G>A p.G766S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs772241000, COSV100687869; called by muse, mutect2, varscan2
- ZFHX4 | c.1494A>C p.K498N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.203); catalogued as rs752025675, COSV99268641; called by muse, mutect2
- ZNF280B | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100840469; called by muse, mutect2, varscan2
- ZNF777 | c.20C>G p.S7* | Nonsense Mutation (SNP) | VAF 42/64 reads (66%) | catalogued as COSV99925429; called by muse, mutect2, varscan2
- CENPC | c.616dup p.R206Kfs*5 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- DENND1B | c.2227A>G p.I743V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELAVL4 | c.475_489del p.I159_I163del | In Frame Del (DEL) | VAF 16/124 reads (13%) | called by mutect2, pindel
- FLNC | c.7463_7483del p.P2488_I2494del | In Frame Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- NRF1 | c.957dup p.I320Yfs*14 | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | called by mutect2, pindel
- PLXNA3 | c.309del p.Y104Mfs*78 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13338G>A p.E4446= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV101291455; called by muse, mutect2, varscan2
- ALPK2 | c.4233G>C p.V1411= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100864902; called by muse, mutect2, varscan2
- ARHGAP21 | c.3843G>A p.L1281= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV57604690, COSV57608627; called by muse, mutect2, varscan2
- B3GALT5 | c.645C>T p.S215= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as rs754346317, COSV100563509; called by muse, mutect2, varscan2
- BRCA2 | c.4158T>C p.D1386= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV101204686; called by muse, mutect2, varscan2
- CACNA1S | c.5616G>A p.R1872= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV100755432; called by muse, mutect2, varscan2
- CLEC12B | c.210C>T p.D70= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100139133; called by mutect2, varscan2
- CNOT3 | c.1242C>T p.S414= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99652393; called by muse, mutect2, varscan2
- CORIN | c.2955C>T p.S985= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs778077028, COSV99904599; called by muse, mutect2, varscan2
- DECR1 | c.831C>T p.L277= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as rs776269139, COSV99616619; called by muse, mutect2, varscan2
- DNAH5 | c.5491T>C p.L1831= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV99455071; called by muse, mutect2, varscan2
- DOCK4 | c.2880C>T p.R960= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1293550396, COSV101448019; called by muse, mutect2
- EPG5 | c.7191C>A p.L2397= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs766126331, COSV99958253; called by muse, mutect2
- FGFR4 | c.1329C>T p.P443= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as rs1240922615, COSV99451074; called by muse, mutect2, varscan2
- GRIN2A | c.3018G>A p.A1006= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs761132463, COSV58037726; called by muse, mutect2, varscan2
- HDAC5 | c.1359G>A p.Q453= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs956984209, COSV99871149; called by muse, mutect2, varscan2
- LARP4 | c.2052C>A p.I684= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as COSV99529765; called by muse, mutect2, varscan2
- LRRK1 | c.1884T>C p.A628= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as COSV99443634; called by muse, mutect2, varscan2
- MMP25 | c.432T>C p.Y144= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs944057777, COSV100339649; called by muse, mutect2, varscan2
- OR51I2 | c.351C>T p.A117= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV100413497; called by muse, mutect2, varscan2
- OR5H1 | c.85C>T p.L29= | Silent (SNP) | VAF 32/291 reads (11%) | catalogued as rs560281040, COSV100641793; called by muse, mutect2, varscan2
- PAQR8 | c.159C>T p.T53= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs1452241577, COSV100658553; called by muse, mutect2, varscan2
- PCDHB15 | c.2076G>A p.V692= | Silent (SNP) | VAF 44/205 reads (21%) | catalogued as COSV99179281; called by muse, mutect2, varscan2
- PDE3A | c.2202A>G p.E734= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100762894; called by muse, mutect2, varscan2
- PDZRN3 | c.1653C>T p.D551= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs759070383, COSV55216847; called by muse, mutect2, varscan2
- PLCE1 | c.1146G>A p.P382= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs769644679, CD066390, COSV53337625; called by muse, mutect2, varscan2
- RADIL | c.288G>A p.A96= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs1392516152, COSV68199991, COSV68200659; called by muse, mutect2, varscan2
- SLC45A3 | c.1590G>T p.L530= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV100901364; called by muse, mutect2
- STARD5 | c.534C>G p.T178= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV100250949, COSV57154928; called by muse, mutect2, varscan2
- UBXN4 | c.273A>G p.E91= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV99739708; called by muse, mutect2, varscan2
- UGT2A1 | c.207G>C p.L69= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV99684999; called by muse, mutect2, varscan2
- UNC5C | c.96C>T p.S32= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV101498061; called by muse, mutect2, varscan2
- ZFR2 | c.2070G>A p.R690= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV99507998; called by muse, mutect2, varscan2
- ZNF124 | c.114T>C p.Y38= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs1319159441, COSV61507048; called by muse, mutect2, varscan2
- ZNF33B | c.1473C>T p.H491= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100847803; called by muse, mutect2, varscan2
- EXOC3 | chr5:442557 T>G | 5'Flank (SNP) | VAF 137/273 reads (50%) | called by muse, mutect2, varscan2
- MIR379 | n.6T>C | RNA (SNP) | VAF 4/52 reads (8%) | catalogued as rs1316049475; called by muse, mutect2
- NT5E | c.1360+411A>G | Intron (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- SFRP1 | c.544+1841C>T | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99617898; called by muse, mutect2, varscan2
- VGLL4 | c.65-41436A>G | Intron (SNP) | VAF 39/103 reads (38%) | catalogued as rs1409721246, COSV99810508; called by muse, mutect2, varscan2
- ZNF207 | c.-133G>T | 5'UTR (SNP) | VAF 30/115 reads (26%) | catalogued as COSV100340724; called by muse, mutect2, varscan2
